Gene-level copy-number profile of tumor specimen TCGA-SR-A6MR-01A from TCGA case TCGA-SR-A6MR, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, malignant; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 41.0 years (14,991 days).
Specimen TCGA-SR-A6MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.fd5dd695-a33e-46fb-84d5-ed494b94912c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SR-A6MR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS.
https://portal.gdc.cancer.gov/files/8eca47e5-8197-4b64-af2a-d6c45aaca5ef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 7,138; copy number 2: 52,665; copy number 3: 4.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:101,786,340–101,787,219, 1 gene: RPSAP19.
- chr4:44,944,015–44,944,961, 1 gene: PRDX4P1.
- chr4:59,833,175–59,834,167, 2 genes: Y_RNA, RNU6-1325P.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr11:54,682,877–54,725,816, 4 genes: OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:112,977,353–112,977,420, 1 gene: RNU7-187P.
- chr12:91,050,491–91,058,024, 1 gene: KERA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,752. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
